Gene-level copy-number profile of tumor specimen TCGA-D6-A4ZB-01A from TCGA case TCGA-D6-A4ZB, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.5 years (22,455 days).
Specimen TCGA-D6-A4ZB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6a798cc7-9914-46cd-afb5-b97b3468266c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A4ZB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/175f16c3-be11-4e3e-9b98-743956d54874

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 15,225; copy number 2: 38,585; copy number 3: 4,375; copy number 4: 1,608; copy number 7: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A4ZB-01A-11D-A253-01): tumor purity 0.44, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr3:73,382,431–73,627,626, 4 genes (within-gene range 0–1): PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:204,065,706–204,507,672, 7 genes, copy number 7: AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1, AC016903.1, AC016903.2.
- chr2:204,668,863–204,678,698, 1 gene, copy number 7: AC007736.1.

Autosomal genes at a single copy (total copy number 1): 12,846. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
